Somatic mutation profile of tumor specimen TCGA-KK-A7B0-01A (aliquot TCGA-KK-A7B0-01A-11D-A32B-08) from TCGA case TCGA-KK-A7B0, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.8 years (24,756 days).
Specimen TCGA-KK-A7B0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 143947bf-c81f-4238-8826-1142197b896c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7B0-11A (Solid Tissue Normal), aliquot TCGA-KK-A7B0-11A-11D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/037224ea-d214-4461-8654-d823b6560089

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.305T>C p.F102S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61652830, COSV61654088, COSV61654168; called by muse, mutect2, varscan2
- ADGRG1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as COSV101113560; called by muse, mutect2, varscan2
- APC | c.1472_1473insT p.H492Pfs*45 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | catalogued as CI130118; called by mutect2, pindel*, varscan2*
- CD5L | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 26/197 reads (13%) | catalogued as COSV100941180; called by muse, mutect2, varscan2
- CD79A | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as rs143511203; ClinVar: not provided; called by muse, mutect2, varscan2
- ENOPH1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV56732632, COSV99908820; called by muse, mutect2, varscan2
- ERP27 | c.799A>C p.K267Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as COSV56763353, COSV99844456; called by muse, mutect2, varscan2
- FN1 | c.3448G>T p.V1150F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as CM142406, COSV100118246, COSV100118283; called by muse, mutect2, varscan2
- FOXJ2 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs773530747, COSV50819231; called by muse, mutect2, varscan2
- HDC | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.605); catalogued as COSV51068664, COSV99984328; called by muse, mutect2, varscan2
- KRTAP1-5 | c.117C>G p.S39R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100721410; called by muse, varscan2
- OR6M1 | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100484182; called by muse, mutect2, varscan2
- OR8K5 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as COSV100537333; called by muse, mutect2
- PCDHB5 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 22/128 reads (17%) | catalogued as COSV99169525; called by muse, mutect2, varscan2
- SHC3 | c.505A>G p.M169V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200962607, COSV101012054; called by muse, mutect2, varscan2
- SLCO4C1 | c.1162G>T p.V388F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100195834; called by muse, mutect2, varscan2
- STAB2 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1053691290, COSV101186301; called by muse, mutect2, varscan2
- UBR2 | c.2711T>G p.I904S | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100867523; called by muse, mutect2, varscan2
- XAB2 | c.2321A>C p.Q774P | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99351960; called by muse, mutect2
- ZNF804A | c.2402C>A p.T801N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV100167896, COSV100170172; called by muse, mutect2, varscan2
- GADL1 | c.829_844del p.V277Tfs*6 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel
- MUC2 | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACTC1 | c.9C>T p.D3= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs535623090, COSV99292135; called by muse, mutect2, varscan2
- CCDC40 | c.792C>A p.S264= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99482210; called by muse, mutect2, varscan2
- CNPY2 | c.363A>G p.Q121= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as COSV99836601; called by muse, mutect2, varscan2
- LRP1B | c.3471C>T p.C1157= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV101260962, COSV67250973; called by muse, mutect2, varscan2
- NFAT5 | c.4065T>C p.S1355= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100591222; called by muse, varscan2
- TTF2 | c.1455C>T p.G485= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs759789310, COSV101037847; called by muse, mutect2, varscan2
- WDR3 | c.1143C>T p.V381= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100832378; called by muse, mutect2, varscan2
